Gene-level copy-number profile of tumor specimen TCGA-XF-A8HF-01A from TCGA case TCGA-XF-A8HF, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 80.2 years (29,288 days).
Specimen TCGA-XF-A8HF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.fb8fbef1-2d43-4c59-9d7b-b3d3cf281bf5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XF-A8HF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a4787831-7ce3-47bf-906f-7866b1c55d42

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 97; copy number 1: 645; copy number 2: 7,224; copy number 3: 23,903; copy number 4: 15,650; copy number 5: 4,599; copy number 6: 4,694; copy number 7: 2,986; copy number 8: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XF-A8HF-01A-11D-A363-01): tumor purity 0.69, ploidy 3.7, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 84 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:65,924,629–66,572,546, 12 genes: AC010359.2, ERBIN, AC010359.1, AC010359.3, AC025442.2, SREK1, AC025442.1, LINC02065, AC092353.1, AC092353.2, LINC02229, PPIAP78.
- chr9:21,638,285–22,214,672, 18 genes: H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr10:87,500,337–88,606,976, 21 genes: AL355334.2, MIR4678, MINPP1, AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS, Y_RNA, LIPJ.
- chr14:68,338,728–68,796,253, 10 genes: AL122013.1, PPIAP6, AL121820.3, AL121820.2, AL121820.1, RPL12P7, AL133313.1, AL132986.1, RNU6-921P, ZFP36L1.
- chr18:70,489,630–72,881,399, 23 genes: AC091305.1, AC091646.1, RN7SL795P, GTSCR1, AC090415.2, AC090415.1, AC091691.3, AC091691.2, AC091691.1, LINC01541, AC090312.1, AC090312.2, LINC01899, AC027458.1, AC069114.1, AC069114.2, CBLN2, HNRNPA1P11, NETO1, AC023301.1, RNA5SP460, MIR548AV, AC091138.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,002 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:170,418,868–170,860,380, 1 gene, copy number 7 (within-gene range 6–7): AC026316.4.
- chr3:170,448,639–170,860,993, 1 gene, copy number 7 (within-gene range 6–7): SLC7A14-AS1.
- chr3:170,653,846–172,401,669, 25 genes, copy number 7 (within-gene range 5–7): AC026316.1, AC026316.3, AC026316.5, AC026316.2, RPL22L1, EIF5A2, AC061708.1, KLF7P1, RNU1-70P, SLC2A2, TNIK, MIR569, Y_RNA, AC092919.1, AC092919.2, RNU6-348P, AC008134.1, PLD1, TMEM212-AS1, TMEM212, TMEM212-IT1, AC055714.1, FNDC3B, RPS27AP8, RN7SL141P.
- chr8:2,726,956–5,911,236, 24 genes, copy number 7: AC246817.1, AC115485.1, AC023296.1, CSMD1, AC026991.1, AC026991.2, RNA5SP251, AC027251.1, AC010941.1, AC022068.1, PAICSP4, AC019176.1, AC019176.2, SNORA70, RN7SL318P, AC007718.1, AC091193.1, RPL23AP54, AC004944.1, AC084768.1, AC084768.2, AC087369.1, AC087369.2, RN7SKP159.
- chr8:35,080,592–102,124,907, 1,074 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr8:102,125,432–119,108,455, 175 genes, copy number 7 (broad region; genes not listed).
- chr11:68,683,779–75,768,647, 250 genes, copy number 7 (broad region; genes not listed).
- chr20:87,250–45,972,203, 1,015 genes, copy number 7 (broad region; genes not listed).
- chr20:46,118,278–64,313,132, 437 genes, copy number 7–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 68. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
